TARGET case TARGET-10-PAMKZB — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8bb50028-c1bc-5d32-8a7a-da7c975ebb71

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 327 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.9 years (5,430 days); Year of diagnosis: 2003; Days to last follow up: 327 days.
   Treatment given: Protocol identifier: AALL0031.

Follow-up (3 entries)
- Days to follow up: 236 days; Days to first event: 236 days; First event: Relapse.
- Days to follow up: 327 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2004.
- Days to follow up: 327 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 107 ×10³/µL.

Biospecimens (8 samples)
- Sample TARGET-10-PAMKZB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAMKZB-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PAMKZB-60.11C, TARGET-10-PAMKZB-60.14C, TARGET-10-PAMKZB-60.1C, TARGET-10-PAMKZB-60.2C, TARGET-10-PAMKZB-60.6C, TARGET-10-PAMKZB-60.8C (6 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Overall Survival Time in Days: 327
- WBC at Diagnosis: 107
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
